Gene-level copy-number profile of tumor specimen HCM-CSHL-0162-C19-01A from HCMI case HCM-CSHL-0162-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.4 years (22,776 days).
Specimen HCM-CSHL-0162-C19-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d207f9a1-ee4a-427b-9165-7fbb2392a2ba.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0162-C19-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/acbbe93d-c951-4657-add7-7d0905129e1f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,704; copy number 2: 32,199; copy number 3: 15,571; copy number 4: 781; copy number 5: 1,531; copy number 6: 124.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,655 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–180,970,762, 2 genes, copy number 6: AC091874.2, AC091874.1.
- chr13:18,467,172–29,888,405, 268 genes, copy number 5–6 (broad region; genes not listed).
- chr13:84,020,327–114,337,626, 380 genes, copy number 5 (broad region; genes not listed).
- chr20:21,265,854–64,327,972, 1,005 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,011. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
